Somatic mutation profile of tumor specimen TCGA-EL-A4K2-01A (aliquot TCGA-EL-A4K2-01A-11D-A257-08) from TCGA case TCGA-EL-A4K2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.7 years (15,962 days).
Specimen TCGA-EL-A4K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaedaabd-828a-49d0-95ef-2970757ed8ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K2-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K2-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43578afe-3684-435f-8b0d-6f1109ede5ca

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 68/178 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CFAP74 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1314099935, COSV54572568; called by muse, mutect2, varscan2
- DNAJC11 | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV50011562; called by muse, mutect2, varscan2
- MLIP | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51435173; called by muse, mutect2, varscan2
- SLC22A7 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV101000839; called by muse, mutect2
- UBC | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1229363186, COSV60060965; called by muse, mutect2
- USP5 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV57532066; called by muse, mutect2, varscan2
- UBR5 | c.8079del p.F2693Lfs*25 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- TBC1D2B | c.2086C>T p.L696= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV56045281; called by muse, mutect2
